Somatic mutation profile of tumor specimen TCGA-VW-A7QS-01A (aliquot TCGA-VW-A7QS-01A-12D-A33T-08) from TCGA case TCGA-VW-A7QS, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 35.1 years (12,820 days).
Specimen TCGA-VW-A7QS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b28189bb-6bfe-4b75-b012-ae7d450f4659.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VW-A7QS-10A (Blood Derived Normal), aliquot TCGA-VW-A7QS-10A-02D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25828456-7f1a-4873-a4b5-f0c146af31d0

The open-access MAF lists 43 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 10, Nonsense Mutation 2, Frame Shift Del 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 73/187 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AKAP9 | c.1164_1167del p.R388Sfs*6 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as rs762979640; called by mutect2, pindel, varscan2
- AL662899.2 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 69/131 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs372125807; called by muse, mutect2, varscan2
- ARHGEF18 | c.1991C>T p.P664L (on ENST00000359920 / NM_001130955.2; = p.P560L on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149572002; called by muse, mutect2, varscan2
- DCHS1 | c.8512A>G p.T2838A | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.366); catalogued as COSV100197818; called by muse, mutect2, varscan2
- F2RL3 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs780756775, COSV50185173; called by muse, mutect2, varscan2
- FBXO11 | c.2111T>A p.I704K (on ENST00000403359 / NM_001190274.2; = p.I620K on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99317113; called by muse, mutect2, varscan2
- GALNT3 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs748580763, COSV101205027; called by muse, mutect2, varscan2
- GLRA3 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 59/122 reads (48%) | catalogued as rs768862714, COSV99928303; called by muse, mutect2, varscan2
- HELLS | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 67/322 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99492468; called by muse, mutect2, varscan2
- HTR3A | c.923A>C p.Y308S | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100248679; called by muse, mutect2, varscan2
- KCNS2 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as rs769042324, COSV99751561; called by muse, mutect2, varscan2
- KCNT2 | c.1592A>G p.N531S | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.101); catalogued as COSV99657266; called by muse, mutect2, varscan2
- LHX5 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.513); catalogued as rs967805412, COSV99922577; called by muse, mutect2, varscan2
- MAST4 | c.4030G>A p.G1344R (on ENST00000403625 / NM_001164664.2; = p.G1155R on NM_015183.3) | Missense Mutation (SNP) | VAF 32/412 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773334015, COSV99846241; called by muse, mutect2
- MTOR | c.6688T>G p.L2230V | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63875963; called by muse, mutect2, varscan2
- MYH7 | c.3340C>T p.R1114C | Missense Mutation (SNP) | VAF 3/59 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204830698, COSV100806789; called by muse, mutect2
- MYO7B | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs936305918, COSV101268412; called by muse, mutect2
- NEB | c.12413C>T p.A4138V | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99428684; called by muse, mutect2, varscan2
- NOTCH1 | c.1180G>T p.G394C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99492449; called by muse, mutect2, varscan2
- OR51G2 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.103); catalogued as rs750568250, COSV58992987; called by muse, mutect2, varscan2
- PARP3 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 51/132 reads (39%) | catalogued as rs750153146, COSV99232811; called by muse, mutect2, varscan2
- PRKCA | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.426); catalogued as rs1191887100, COSV99435874; called by muse, mutect2, varscan2
- RNASE13 | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 96/230 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs533949543, COSV100409687; called by muse, mutect2, varscan2
- SH3KBP1 | c.424G>T p.G142W | Missense Mutation (SNP) | VAF 15/259 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65640393, COSV65643538; called by muse, mutect2
- SLC26A4 | c.1639A>C p.I547L | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as CM1314668, COSV99707570; called by muse, mutect2, varscan2
- SLC9A2 | c.1631G>A p.R544Q | Missense Mutation (SNP) | VAF 106/251 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs766000036, COSV99296945, COSV99297057; called by muse, mutect2, varscan2
- ZHX3 | c.946A>G p.N316D | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs745998273, COSV100476876; called by muse, mutect2, varscan2
- ZNF462 | c.5555T>G p.F1852C | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99473563; called by muse, mutect2
- ZNF558 | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV100037768, COSV56864379; called by muse, varscan2
- NOTCH1 | c.1360_1362del p.N454del | In Frame Del (DEL) | VAF 62/138 reads (45%) | called by mutect2, pindel, varscan2
- USP25 | c.1922_1923del p.F641Wfs*4 | Frame Shift Del (DEL) | VAF 63/218 reads (29%) | called by mutect2, pindel, varscan2
- CLCN3 | c.492G>A p.A164= | Silent (SNP) | VAF 83/175 reads (47%) | catalogued as rs774017125, COSV61628158; called by muse, mutect2, varscan2
- CRLF2 | c.279C>T p.D93= | Silent (SNP) | VAF 26/232 reads (11%) | catalogued as rs1422648367, COSV101053865; called by muse, mutect2, varscan2
- DGAT2L6 | c.813C>T p.R271= | Silent (SNP) | VAF 70/170 reads (41%) | catalogued as rs746570087, COSV100284169; called by muse, mutect2, varscan2
- ITIH5 | c.1026A>G p.V342= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as rs541001933, COSV99906043; called by muse, mutect2, varscan2
- MYCBP2 | c.10176G>A p.P3392= (on ENST00000357337; = p.P3430= on NM_015057.5) | Silent (SNP) | VAF 121/272 reads (44%) | catalogued as rs767157165, COSV62038524; called by muse, mutect2, varscan2
- MYO5B | c.4548C>T p.N1516= | Silent (SNP) | VAF 67/141 reads (48%) | catalogued as rs757756648, COSV99546499; called by muse, mutect2, varscan2
- NINL | c.159C>A p.L53= | Silent (SNP) | VAF 120/302 reads (40%) | catalogued as COSV99626535; called by muse, mutect2, varscan2
- OR10X1 | c.495C>T p.C165= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV100936629, COSV100936723; called by muse, mutect2, varscan2
- SHROOM2 | c.4218G>A p.A1406= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs756695165, COSV101099137; called by muse, mutect2, varscan2
- TLR5 | c.624G>A p.L208= | Silent (SNP) | VAF 66/167 reads (40%) | catalogued as COSV100643412; called by muse, mutect2, varscan2
- C3P1 | n.2472A>G | RNA (SNP) | VAF 50/311 reads (16%) | called by muse, mutect2, varscan2
